Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABU7, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABU7-TTP1-A (Primary Tumor).

[page 1 of 9]
Patient Name: [REDACTED]

MR #: [REDACTED]

Account: [REDACTED]

Collection Date: [REDACTED]

+0

Date of Birth: [REDACTED]

Age: [REDACTED]

Sex: [REDACTED]

Received Date: [REDACTED]

+0

Submitting Physician: [REDACTED]

Location: [REDACTED]

Physicians

Supplemental Report

3. PCR mutation analysis for BRAF was performed at [REDACTED] with the following results:

NOT DETECTED

(See attached report.)

Tissue Source

1. LYMPH NODE (SENTINEL), left axillary-Excisional Biopsy
2. LYMPH NODE (SENTINEL), left axillary #2-Excisional Biopsy
3. SKIN, left shoulder-Excisional Biopsy

Clinical Information

1. -3. Melanoma

Gross Description

1. Received fresh by the pathologist in the operating room, labeled "sentinel node left axilla" is a 2.6 x 1 x 0.8 cm tan-pink lymph node that is trisected. Touch prep smears are made. The specimen is entirely submitted as A and B. 2/3 [REDACTED]

Immediate Cytologic Evaluation

2.6 x 1 x 0.8 cm tan-brown lymph node, trisected and touch preps made.

TPDX: No tumor identified.

Pathologist

(Immediate Cytologic Evaluation Signed [REDACTED])

+0

2. Received fresh by the pathologist in the operating room, labeled "second sentinel node left axilla" is a 1 x 1 x 0.6 cm portion of yellow fatty tissue that contains a 0.3 x 0.2 x 0.2 cm tan-pink lymph node. The specimen is bisected. Touch prep smears are made. The specimen is entirely submitted in one cassette. 1/3 [REDACTED]

Immediate Cytologic Evaluation

1 cm portion of fat containing a possible 0.3 x 0.2 x 0.2 cm lymph node.

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 2 of 9]
Gross Description (continued)

TPDX: No tumor identified.

Pathologist

(Immediate Cytologic Evaluation Signed [REDACTED] +0

3. Received in formalin, labeled "melanoma from left shoulder" is a 4.4 x 3.5 cm ellipse of wrinkled tan-white skin excised to a depth of 1 cm. In the center of the specimen, there is a 1.9 x 1.5 cm tan brown irregular lesion with a central hypopigmented area. There are a few 0.4 cm tan pink scarred areas along the edges of the lesion. The specimen is serially sectioned and entirely submitted as A-K, with the ends as A and a bisected section as H and I. 11/multiple [REDACTED]

Diagnosis

1. LYMPH NODE (SENTINEL), left axillary-Excisional Biopsy
ONE LYMPH NODE, NEGATIVE FOR METASTATIC MELANOMA BY H&E AND
IMMUNOPEROXIDASE STAINS (0/1)

2. LYMPH NODE (SENTINEL), left axillary #2-Excisional Biopsy
METASTATIC MELANOMA, PRESENT IN ONE LYMPH NODE (1/1)

Comment: The metastatic melanoma is seen best with immunoperoxidase stains, and is present as a few scattered single and clustered tumor cells, with the largest focus measuring 0.3 mm.

3. SKIN, left shoulder-Excisional Biopsy
MALIGNANT MELANOMA

-Breslow thickness: 3mm

-Clark's level: IV/V

-Mitoses: 1 per millimeter square

-Ulceration: Not present

-Regression: Partial regression identified

-Lymphovascular invasion: Not identified

-Margins: Not involved by invasive or in situ melanoma

Comment: The previous biopsy report has been reviewed. Based on the current and previous findings, the AJCC pathologic stage is IIIA (T3a N1a).

Electronic Signature

Pathologist and Dermatopathologist
(Case signed [REDACTED] +2

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 3 of 9]
Ancillary Studies

Immunohistochemical studies were performed on paraffin embedded sections using the Refine Detection (Leica Microsystems) immunoperoxidase method. The results are as follows:

Antibody	Result
S100	+ specimen 2, - specimen 1
melan-a	+ specimen 2, - specimen 1
hmb45	+ specimen 2, - specimen 1

External and internal controls stain appropriately.

Date performed [REDACTED] +1 Pathologist: [REDACTED]

S
U
R
G
I
C
A
L

P
A
T
H
O
L
O
G
Y

R
E
P
O
R
T

[page 4 of 9]
PET CT Whole Body Subsequent
Reason for Exam: assess for
extent of disease following
radiation therapy.

Date: [REDACTED] +384

CC: [REDACTED]

Imaging Result

HISTORY: [REDACTED] with metastatic melanoma. Evaluate extent of disease following radiation therapy.

TECHNIQUE: The patient's blood glucose level was measured to be 101 mg/dL. At approximately one hour following intravenous injection of 15.2 mCi of 18 F-fluorodeoxyglucose, an attenuation corrected PET scan was performed from the cranial vertex through the lower extremities. Low dose CT imaging was utilized for attenuation correction and anatomic localization. Comparison is made to a previous study of [REDACTED] +328

FINDINGS:

The scalp and facial region demonstrate no abnormal focus or region of tracer accumulation. In the right lateral mass of C1, there is a small focus of increased tracer accumulation. In the left lateral mass of C2, there is a focus of increased tracer accumulation of maximum standard uptake value 3.4. At the cervicothoracic junction within the C7, T1 and T2 vertebra, multiple foci of intense tracer accumulation are seen of maximum standard uptake value 13.2. There is no other abnormal focus or region of tracer accumulation in the neck.

In the thorax, multiple osseous lesions are demonstrated. These include a lesion of the left clavicular head of maximum standard uptake value 18.6, a large lesion of the sternum of maximum standard uptake value of 35.3 and a lesion within the T11 vertebral body of maximum standard uptake value 20.0. Lesions of the right proximal humerus and multiple lesions of the ribs are also demonstrated as well as additional foci of increased tracer accumulation within the thoracic spine.

In the abdomen, there is a lesion in the right hepatic lobe seen on PET CT image 161 measuring approximately 2.8 cm diameter and demonstrating intense tracer accumulation of maximum standard uptake value 7.4. Multiple osseous metastases are demonstrated in the region of the pelvis, and there is a focus of increased tracer accumulation in the L5 vertebral body of maximum standard uptake value 3.4. In the right proximal femora, there is a focus of intense tracer accumulation of maximum standard uptake value 5.6.

The upper and lower extremities demonstrate no other definitive abnormality by PET.

Review of the attenuation correction CT images was performed. Coronary arterial calcifications are demonstrated. Coarse calcifications of the prostate gland are noted.

Impression:

1. Numerous diffuse osseous metastases are increased compared to the previous study.
2. There is a new intrahepatic lesion consistent with a metastasis.
3. There is no other evidence of malignancy on the current study.

Reported And Signed By [REDACTED]

[page 5 of 9]
Signed By:

Technologist:

[Redacted signature line]

[page 6 of 9]
PET CT Whole Body Subsequent
Reason for Exam: assess for
melanoma response to Yervoy

Date: [REDACTED] +483

CC:

Imaging Result

CLINICAL DATA: Assess for melanoma response.

Approximately 1 hour after the intravenous administration of 14.60 mCi F-18 fluorodeoxyglucose, an attenuation corrected imaging study was performed with images obtained from the level of the top of the skull to the feet including the upper extremities on today's study. The study is compared with the previous PET study dated [REDACTED] injection made by intravenous injection into the left hand vein. Patient's blood sugar 103 mg/dL.

Compared to the prior study in the neck there is some activity persisting at the C2 level to the left of midline which shows an SUV of 2.8. This is seen in the left lateral mass and although slightly less in its most prominent portion on the prior study if there is slightly more prominent lateral activity seen. The maximal activity in this area is measured to be 2.8. On the previous study the activity was measured at 3.4 SUV. In the remainder of the cervical spine no suspicious uptake is seen with overall improvement compared to the prior study

In the chest the prior study showed multiple areas of activity corresponding to bony structures which have essentially resolved with no suspicious uptake seen in the chest on today's exam.

In the abdomen the previous study had demonstrated a hepatic lesion which is no longer identified on today's exam. No suspicious uptake associated with the bony structures otherwise noted.

In the pelvis no suspicious uptake is seen. With attention directed to the extremities no suspicious uptake in the upper extremities is seen. In the right lower extremity in the medial right shin there is focal activity seen on the surface of the skin anteromedially with an SUV of 2.4. This was not present on the prior study. There does appear to be some associated finding in the skin/subcutaneous fat on the attenuation CT raising suspicion for skin neoplastic lesion. This is best seen on image 151 and has a transverse measurement of approximately 15 mm.

IMPRESSION: Marked improvement compared to the prior study. There is minimal bony uptake associated with the left C2 vertebral body.

Inferiorly there is minimal activity along the surface of the skin at the right medial calf. As this does appear to show some minimal tissue thickening on the skin anteromedially at this location this could represent a superficial skin lesion and does represent a change compared to the prior study.

Reported And Signed By [REDACTED]

Signed By: [REDACTED] +483

[page 7 of 9]
Technologist:

[Redacted Signature]

[page 8 of 9]
PET CT Whole Body Subsequent
Reason for Exam: evaluate for
extent of metastatic melanoma
following Yervoy therapy

Date:

+706

Imaging Result

HISTORY: Evaluate for extent of metastatic melanoma.

TECHNIQUE: The patient's blood glucose level was measured to be 95 mg/dL. At approximately one hour following intravenous injection of 13.0 mCi of 18 F-fluorodeoxyglucose, an attenuation corrected PET scan was performed from the cranial vertex to the lower extremities. Low dose CT imaging was utilized for attenuation correction and anatomic localization. Comparison is made to previous studies of [REDACTED] and [REDACTED]

+580

+483

FINDINGS: The scalp and facial region demonstrate no abnormal tracer activity. Physiologic salivary activity is present in the oropharynx. No abnormal focus or region of tracer accumulation is seen in the neck.

In the thorax, physiologic mediastinal blood pool activity and physiologic left ventricular activity are demonstrated. At the approximately T7 level of the thoracic spine, there is a new focus of intense tracer accumulation projecting within the vertebral body measuring approximately 1.7 cm in transverse dimension and demonstrating a maximum standard uptake value of 12.1. This finding represents an interval change from previous studies. There is no other abnormal focus or region of tracer accumulation in the thorax to indicate malignancy.

The upper extremities demonstrate no abnormal tracer accumulation.

In the abdomen, physiologic hepatic, splenic and gastric activity are demonstrated. Tracer excretion is seen in the kidneys ureters and bladder, the normal route of tracer excretion. Physiologic colonic activity is demonstrated. There is no abnormal focus or region of tracer accumulation in the abdomen or pelvis to indicate evidence of malignancy.

The lower extremities demonstrate no definite abnormal tracer activity.

Review of the attenuation correction CT images was performed. Prostatic calcifications are demonstrated. Metallic fusion of the lower lumbar spine is demonstrated. Multilevel thoracic and lumbar spinal degenerative changes are present. Coronary arterial calcifications are demonstrated. There is equivocal mural thickening of the bladder. Multiple coarse calcifications are noted in the prostate gland.

IMPRESSION:

1. There is a new solitary focus of intense tracer accumulation within the vertebral body at the approximately T7 level of the thoracic spine suspicious for malignancy. If clinically indicated, correlation with pre and postcontrast imaging of the thoracic spine may be useful for further evaluation of this finding.
2. There is no other evidence of malignancy on the current study.

Reported And Signed By: [REDACTED]

[page 9 of 9]
Signed By: [REDACTED] +707
Technologist: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 974b0f3a-03c0-4302-b396-5f2b197139f4 (ER0143 ER-ABU7 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).